Somatic mutation profile of tumor specimen C3L-06807-54 (aliquot CPT0395130002) from CPTAC case C3L-06807, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 68.1 years (24,887 days).
Specimen C3L-06807-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb51f9f5-504d-4278-9da1-a6e8a1740bfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06807-51 (Buccal Cell Normal), aliquot CPT0395180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b3a6fd3-5adc-465c-83ee-d74193ac4408

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 57/387 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267606708, CM105119, COSV50629675, COSV50657904, COSV50660979; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- EZH2 | c.2054G>A p.R685H (on ENST00000460911 / NM_001203247.2; = p.R690H on NM_004456.5) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554481435, COSV57446082; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKAR | c.1189T>A p.L397M | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2
- STAG2 | c.3243dup p.R1082Tfs*5 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
